Somatic mutation profile of tumor specimen TCGA-AR-A0U2-01A (aliquot TCGA-AR-A0U2-01A-11D-A10G-09) from TCGA case TCGA-AR-A0U2, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.6 years (17,390 days).
Specimen TCGA-AR-A0U2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 976304dc-a763-4b7a-8b62-2f0ed675c22f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0U2-10A (Blood Derived Normal), aliquot TCGA-AR-A0U2-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61e8e65a-1bfb-4457-8581-bb139625bece

The open-access MAF lists 52 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 8, Frame Shift Ins 3, Nonsense Mutation 1, 3'UTR 1, Splice Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXL | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs374699228; called by muse, mutect2, varscan2
- GATA3 | c.1092A>T p.R364S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60517825; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 32/41 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1271007842, COSV51568513; called by muse, mutect2, varscan2
- AEBP1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs771452124, COSV56257196; called by muse, mutect2, varscan2
- AURKA | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV57170312; called by muse, mutect2, varscan2
- CAMKMT | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1020249685, COSV65923997; called by muse, mutect2, varscan2
- CD163L1 | c.1217T>G p.V406G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58025063; called by muse, mutect2, varscan2
- CNTNAP4 | c.1635C>G p.D545E | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56685530, COSV56700971; called by muse, mutect2, varscan2
- CSTF2T | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs750598423, COSV58656612; called by muse, mutect2, varscan2
- DOP1A | c.7060C>T p.R2354* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV52718460; called by muse, mutect2, varscan2
- ERICH3 | c.2565dup p.S856Vfs*17 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | catalogued as rs776195150; called by mutect2, pindel, varscan2
- GABRA5 | c.41A>T p.N14I | Missense Mutation (SNP) | VAF 173/411 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV59486058; called by muse, mutect2, varscan2
- GATA3 | c.1221dup p.P408Afs*99 | Frame Shift Ins (INS) | VAF 26/67 reads (39%) | catalogued as COSV100650835, COSV100651341, COSV60515158, COSV60515274, COSV60515375, COSV60517941; called by mutect2, pindel, varscan2
- GRXCR2 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.907); catalogued as COSV65061955; called by muse, mutect2, varscan2
- HIPK2 | c.2108C>G p.A703G | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV61232888; called by muse, mutect2, varscan2
- IGF1R | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99148014; called by muse, mutect2
- IGKV3D-20 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs929752835; called by muse, mutect2, varscan2
- IMPDH1 | c.155C>A p.T52N (on ENST00000470772 / NM_001142573.2; = p.T137N on NM_000883.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV58318088; called by muse, mutect2, varscan2
- KIAA1549 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as rs777901817, COSV54329063; called by muse, mutect2, varscan2
- MMP2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs759302357, COSV54602409; called by muse, mutect2
- MTF2 | c.1188dup p.G397Rfs*23 | Frame Shift Ins (INS) | VAF 17/60 reads (28%) | catalogued as rs759847587; called by mutect2, varscan2
- NLRP4 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV56723597; called by muse, mutect2, varscan2
- OR2AK2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs113103144; called by muse, mutect2, varscan2
- OSBPL3 | c.819C>A p.H273Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100514649, COSV57662684; called by muse, mutect2, varscan2
- PI4KB | c.2380G>A p.D794N (on ENST00000368873 / NM_001369623.1; = p.D806N on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55019364; called by muse, mutect2, varscan2
- PLXNA1 | c.3988C>T p.R1330W | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52524271; called by muse, mutect2, varscan2
- PPP2R5C | c.1327-1G>A p.X443_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | catalogued as rs751329156, COSV58276639; called by muse, mutect2, varscan2
- PRMT6 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.254); catalogued as COSV63656547; called by muse, mutect2, varscan2
- SEC14L4 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs780473734, COSV55401623; called by muse, mutect2, varscan2
- SENP7 | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58609783, COSV58619872; called by muse, mutect2, varscan2
- SLC7A13 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139761067; called by muse, mutect2, varscan2
- THSD7B | c.2799C>A p.N933K | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55739251; called by muse, mutect2, varscan2
- USH2A | c.14101G>A p.E4701K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs372966682, COSV56431603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR24 | c.983G>A p.R328Q (on ENST00000248142; = p.R198Q on NM_032259.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1313629797, COSV50202365, COSV99555987; called by muse, mutect2, varscan2
- WDR75 | c.1559T>C p.I520T | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV59107091; called by muse, mutect2, varscan2
- ZFP37 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs757370907, COSV65285777, COSV65288791; called by muse, mutect2
- ZNF233 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV61934852; called by muse, mutect2, varscan2
- ZNF687 | c.2508C>A p.F836L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55021417; called by muse, mutect2, varscan2
- ZNF823 | c.278C>A p.P93H (on ENST00000341191 / NM_001297610.2; = p.P49H on NM_017507.2) | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as COSV57873267, COSV57876402; called by muse, mutect2, varscan2
- FSD2 | c.754_756del p.E252del | In Frame Del (DEL) | VAF 27/186 reads (15%) | called by mutect2, pindel, varscan2
- RECQL | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C5 | c.1905G>A p.G635= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV56332268; called by muse, mutect2, varscan2
- HTN3 | c.108G>A p.K36= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV66879842; called by muse, mutect2, varscan2
- IL13RA2 | c.915C>T p.C305= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV54567667; called by muse, mutect2, varscan2
- KDM5A | c.735G>A p.G245= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs1275662898, COSV66996500; called by muse, mutect2, varscan2
- NCAM2 | c.2499C>T p.D833= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs372679606, COSV53098851; called by muse, mutect2
- OLFML1 | c.684T>C p.H228= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV55082585; called by muse, mutect2, varscan2
- PFKP | c.1425C>T p.S475= | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as COSV66901762; called by muse, mutect2, varscan2
- PPP1R3A | c.1065G>T p.G355= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV52893485; called by muse, mutect2, varscan2
- MC3R | c.-52C>A | 5'UTR (SNP) | VAF 13/98 reads (13%) | catalogued as COSV99710383; called by mutect2, varscan2
- TRAC | c.*133dup | 3'UTR (INS) | VAF 24/108 reads (22%) | catalogued as rs747854238; called by mutect2, varscan2
